Surgical pathology report (de-identified scan), TCGA case TCGA-D7-5577, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D7-5577-01A (Primary Tumor).

[page 1 of 2]
Examination: Histopathological examination

Material: Total organ resection - stomach

TCGA-D7-5577

Material collected on:

Material received on:

Clinical diagnosis: Adenocarcinoma ventriculi G2, intestinal type, invasive tumour of the gastric body.

Examination performed on:

Macroscopic description:

Sent material consisting of the stomach, having been cut out along the greater curvature, sized 15 x 15.5 cm with the omentum sized 30 x 14 cm.

Ulcerous tumour on the lesser curvature sized 5 x 6 x 1.1 cm. Distance from the proximal end 0.7 cm, from distal end, 8 cm.

Microscopic description:

Adenocarcinoma tubulare G2.

Tumour penetrated the full thickness of the stomach wall and peritoneal fat tissue reaching the peritoneum membrane.

Surgical incision lines off cancer invaded area. Invasio carcinomatosa vassorum. Reactio lymphocytaria peritumoralis.

Mucosa free of cancer, showing features of chronic inflammation. Omentum sine metastasibus lien sccessorius.

LYMPH NODES:

- periorificial: metastases carcinomatosa in lymphonodis (No XII/XXI).

Infiltratio carcinomatosa capsulae lymphonodorum et telae adiposae perinodalis.

- of lesser curvature: metastases carcinomatosa in lymphonodis (No II/II).

Infiltratio carcinomatosa capsulae lymphonodorum et telae adiposae perinodalis.

- of greater curvature: metastases carcinomatosa in lymphonodis (No II/III).

Infiltratio carcinomatosa capsulae lymphonodorum et telae adiposae perinodalis.

- peripyloric: metastases carcinomatosa in lymphonodis (No III/VIII).

Infiltratio carcinomatosa capsulae lymphonodorum et telae adiposae perinodalis.

Examination result:

Adenocarcinoma tubulare ventriculi.

Metastases carcinomatosa in lymphonodis NO XIX/XXIV.

G2, pT2b, pN3 ty pus intestinalis sec. lauren.

TUBULAR ADENOCARCINOMA OF THE STOMACH - INTESTINAL TYPE (S. LAUREN)

METASTATIC LYMPH NODES (XIX/XXIV)

Compliance validated by:

[page 2 of 2]
Examination performed on:

Results of immunohistochemical examination:

HER2 protein stained with HercepTest™ by DAKO.

Negative reaction in invasive cancerous cells (Score = 0)

Source: NCI Genomic Data Commons file 21318b15-704c-46cb-a730-06b77a1d18dc (TCGA-D7-5577.C0156B0A-0F9B-48A6-AFE3-62E065C6DF8E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).